Somatic mutation profile of tumor specimen C3L-07622-01 (aliquot CPT0452310006) from CPTAC case C3L-07622, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 58.4 years (21,337 days).
Specimen C3L-07622-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 145f4881-a5ab-48c9-ad3b-f4445ab9374c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07622-32 (Blood Derived Normal), aliquot CPT0452460004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02e57128-debf-4ace-a11e-6f22733b5fd5

The open-access MAF lists 315 somatic variants for this specimen: 217 protein-altering or splice-affecting, 78 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 205, Silent 78, Intron 13, Nonsense Mutation 10, 5'Flank 3, 3'UTR 2, 5'UTR 1, RNA 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 26/352 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ABCB11 | c.3427G>A p.D1143N | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as rs1182925965; called by muse, mutect2
- ABCC9 | c.3767T>G p.L1256R | Missense Mutation (SNP) | VAF 18/361 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53963674; called by muse, mutect2
- ADAMTS20 | c.14A>C p.K5T | Missense Mutation (SNP) | VAF 26/414 reads (6%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.559); catalogued as COSV101240345; called by muse, mutect2
- ADRA1A | c.406A>C p.T136P | Missense Mutation (SNP) | VAF 40/593 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as rs1292727649; called by muse, mutect2
- ARHGAP33 | c.2491G>A p.G831R | Missense Mutation (SNP) | VAF 42/755 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV99138319; called by muse, mutect2
- ASB15 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs772843519; called by muse, mutect2
- BARX1 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 26/773 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.114); catalogued as COSV54159386; called by muse, mutect2
- BRCA1 | c.5000A>C p.K1667T | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV58784324; called by muse, mutect2, varscan2
- CDC42BPB | c.4736G>A p.R1579K | Missense Mutation (SNP) | VAF 26/452 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as rs1264728476; called by muse, mutect2
- CENPE | c.4032A>G p.I1344M | Missense Mutation (SNP) | VAF 30/400 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.667); catalogued as rs1188535627; called by muse, mutect2
- CILP2 | c.2899G>A p.G967S | Missense Mutation (SNP) | VAF 80/750 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs771429826, COSV52276419; called by muse, mutect2
- CIT | c.1781T>C p.L594P | Missense Mutation (SNP) | VAF 18/464 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.136); catalogued as rs1442201508, COSV55885012; called by muse, mutect2
- CNGB1 | c.3649G>A p.E1217K | Missense Mutation (SNP) | VAF 50/856 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1056514077, COSV51903816; called by muse, mutect2
- CNTN4 | c.2642A>C p.N881T | Missense Mutation (SNP) | VAF 66/481 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV61872563; called by muse, mutect2, varscan2
- COL12A1 | c.4795C>T p.R1599* | Nonsense Mutation (SNP) | VAF 18/388 reads (5%) | catalogued as COSV100485159, COSV59401096; called by muse, mutect2
- COL19A1 | c.521T>C p.L174P | Missense Mutation (SNP) | VAF 45/510 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59564296; called by muse, mutect2
- CRAMP1 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 43/461 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1189367719; called by muse, mutect2
- CYP7A1 | c.886T>C p.W296R | Missense Mutation (SNP) | VAF 25/369 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1212431115; called by muse, mutect2
- DBT | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 39/448 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as rs750594890, CM015223; called by muse, mutect2
- DMD | c.3505A>G p.M1169V | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs367683746; called by muse, mutect2, varscan2
- DPP4 | c.1456G>C p.V486L | Missense Mutation (SNP) | VAF 21/367 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV62108150; called by muse, mutect2
- FAF1 | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 29/320 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs147358189, COSV65637384; called by muse, mutect2
- FAM47C | c.2017A>G p.T673A | Missense Mutation (SNP) | VAF 40/396 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV63729255; called by muse, mutect2
- FAN1 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 34/574 reads (6%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs773116536, COSV104423954; called by muse, mutect2
- FBXL4 | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 31/482 reads (6%) | catalogued as COSV57746495; called by muse, mutect2
- FKBP8 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 43/701 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs552738926; called by muse, mutect2
- FSTL5 | c.1884A>C p.K628N | Missense Mutation (SNP) | VAF 12/281 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60220481; called by muse, mutect2
- FUCA2 | c.1292T>C p.L431P | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99136314; called by muse, mutect2
- GFRA1 | c.1135G>A p.G379R | Missense Mutation (SNP) | VAF 28/528 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100816313; called by muse, mutect2
- GRAMD1B | c.2153A>G p.Q718R | Missense Mutation (SNP) | VAF 28/425 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.628); catalogued as rs1162502089; called by muse, mutect2
- HOXA6 | c.252C>A p.D84E | Missense Mutation (SNP) | VAF 52/642 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs761136741; called by muse, mutect2
- JPH2 | c.1000G>A p.G334S | Missense Mutation (SNP) | VAF 76/836 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1235114984, COSV65904248; called by muse, mutect2
- LHX8 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 25/547 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1320852521, COSV53954991, COSV99634399; called by muse, mutect2
- LYG1 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); catalogued as rs267599508, COSV57915233; called by muse, mutect2
- MAK | c.1171A>G p.S391G | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1342658202; called by muse, mutect2
- MAP7 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 41/572 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs769620147; called by muse, mutect2
- MCM4 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 28/460 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as COSV50627834; called by muse, mutect2
- MDGA2 | c.2207G>A p.R736Q (on ENST00000399232 / NM_001113498.2; = p.R438Q on NM_182830.4) | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.981); catalogued as rs370464495; called by muse, mutect2
- MFN1 | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 19/263 reads (7%) | SIFT tolerated (0.95); PolyPhen benign (0.012); catalogued as COSV99764526; called by muse, mutect2
- MGAT5B | c.820C>T p.Q274* | Nonsense Mutation (SNP) | VAF 48/378 reads (13%) | catalogued as COSV56925357; called by muse, mutect2, varscan2
- MSANTD1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 32/458 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as rs750864012; called by muse, mutect2
- MTERF4 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 29/417 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs1056529525, COSV54088662; called by muse, mutect2
- MTSS2 | c.1355C>T p.T452M | Missense Mutation (SNP) | VAF 49/640 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs760420108, COSV99852046; called by muse, mutect2
- MUSK | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 33/334 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369558015; called by muse, mutect2
- MYH1 | c.3611T>C p.V1204A | Missense Mutation (SNP) | VAF 46/568 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs756775939; called by muse, mutect2
- MYH8 | c.4993C>T p.R1665W | Missense Mutation (SNP) | VAF 34/518 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs367601078, COSV101238483; called by muse, mutect2
- MYO16 | c.476G>A p.G159E | Missense Mutation (SNP) | VAF 23/319 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480159751; called by muse, mutect2
- NATD1 | c.290A>C p.K97T | Missense Mutation (SNP) | VAF 42/574 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV67541137; called by muse, mutect2
- NKX2-4 | c.889G>A p.G297S | Missense Mutation (SNP) | VAF 53/857 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs977074895; called by muse, mutect2
- NNT | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 30/431 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as rs200498161; called by muse, mutect2
- OR7G1 | c.911T>C p.L304P | Missense Mutation (SNP) | VAF 21/327 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV53318418; called by muse, mutect2
- P2RX7 | c.1423G>T p.V475F | Missense Mutation (SNP) | VAF 54/531 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as rs367838751, COSV55857014; called by muse, mutect2, varscan2
- PGGT1B | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.292); catalogued as COSV99685921; called by muse, mutect2
- PLD5 | c.1360T>G p.F454V (on ENST00000442594; = p.F392V on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/309 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.23); catalogued as COSV59134222; called by muse, mutect2
- PPARGC1A | c.1816A>G p.S606G | Missense Mutation (SNP) | VAF 23/397 reads (6%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1031447027; called by muse, mutect2
- PRUNE2 | c.4281A>C p.K1427N | Missense Mutation (SNP) | VAF 40/452 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV65039865; called by muse, mutect2
- QRFPR | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 67/796 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs764292227, COSV57678487; called by muse, mutect2
- RRP15 | c.533A>G p.Q178R | Missense Mutation (SNP) | VAF 26/323 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs987913740; called by muse, mutect2
- SCD5 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 34/538 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV100124388; called by muse, mutect2
- SEC16A | c.6127G>A p.E2043K | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as rs373011807; called by muse, mutect2
- SIPA1L2 | c.4205A>C p.K1402T | Missense Mutation (SNP) | VAF 28/470 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.813); catalogued as rs766855272; called by muse, mutect2
- SLC13A4 | c.1462T>G p.W488G | Missense Mutation (SNP) | VAF 28/365 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62460834; called by muse, mutect2
- SLC16A6 | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 31/414 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs893938179; called by muse, mutect2
- SLC5A8 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 33/477 reads (7%) | catalogued as COSV101610607, COSV73310684; called by muse, mutect2
- SOGA1 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 51/877 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.711); catalogued as rs1369010053; called by muse, mutect2
- SPATA21 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 38/482 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.346); catalogued as rs761537330; called by muse, mutect2
- SPTA1 | c.278A>C p.K93T | Missense Mutation (SNP) | VAF 17/339 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63751974; called by muse, mutect2
- SYNE1 | c.2528G>A p.R843H (on ENST00000367255 / NM_182961.4; = p.R850H on NM_033071.3) | Missense Mutation (SNP) | VAF 34/440 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs191723029, COSV54927660; ClinVar: uncertain significance; called by muse, mutect2
- TCL1B | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 25/503 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV61551811; called by muse, mutect2
- TTN | c.30273A>C p.K10091N (on ENST00000591111; = p.K9164N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/301 reads (6%) | PolyPhen benign (0.031); catalogued as COSV59882983, COSV60182355; called by muse, mutect2
- TTN | c.19156C>T p.R6386* (on ENST00000591111; = p.R5459* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 36/524 reads (7%) | catalogued as COSV100611746, COSV60075599; called by muse, mutect2
- WASF3 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 48/727 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.808); catalogued as rs146594472, COSV58963222; called by muse, mutect2
- WNT10B | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 31/351 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372388862; called by muse, mutect2
- ZNF606 | c.2339T>G p.L780R | Missense Mutation (SNP) | VAF 20/364 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.603); catalogued as COSV58705833; called by muse, mutect2
- ACTN4 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 33/612 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.195); called by muse, mutect2
- ADAM28 | c.1157T>G p.F386C | Missense Mutation (SNP) | VAF 29/412 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- AFAP1L1 | c.1901A>T p.E634V | Missense Mutation (SNP) | VAF 26/506 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2
- ALB | c.206A>C p.E69A | Missense Mutation (SNP) | VAF 23/362 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.066); called by muse, mutect2
- ANKRD50 | c.3547T>C p.S1183P | Missense Mutation (SNP) | VAF 36/495 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); called by muse, mutect2
- ANTXR1 | c.223A>G p.S75G | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.189); called by muse, mutect2
- ARID1A | c.1690C>T p.Q564* | Nonsense Mutation (SNP) | VAF 34/581 reads (6%) | called by muse, mutect2
- ARMCX5 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 26/228 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATP1B4 | c.252G>T p.Q84H | Missense Mutation (SNP) | VAF 54/319 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATP2A2 | c.2520C>A p.G840= | Splice Region (SNP) | VAF 17/304 reads (6%) | called by muse, mutect2
- ATP4B | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT tolerated (1); PolyPhen possibly damaging (0.891); called by muse, mutect2
- ATR | c.4680T>A p.D1560E | Missense Mutation (SNP) | VAF 15/364 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2
- BCAS3 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 41/286 reads (14%) | called by muse, mutect2, varscan2
- BTBD8 | c.2530G>T p.A844S (on ENST00000636805 / NM_001376131.1; = p.A331S on NM_015237.4) | Missense Mutation (SNP) | VAF 33/450 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.049); called by muse, mutect2
- C15orf40 | c.68T>G p.L23R | Missense Mutation (SNP) | VAF 34/574 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.006); called by muse, mutect2
- C17orf78 | c.59A>G p.D20G | Missense Mutation (SNP) | VAF 26/337 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.42); called by muse, mutect2
- CAV2 | c.193T>C p.S65P | Missense Mutation (SNP) | VAF 44/520 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CC2D2A | c.2113T>C p.F705L | Missense Mutation (SNP) | VAF 26/456 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC73 | c.1884T>G p.D628E | Missense Mutation (SNP) | VAF 27/322 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0.003); called by muse, mutect2
- CDCA3 | c.236A>G p.K79R | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.372); called by muse, mutect2
- CDH4 | c.1427A>C p.N476T | Missense Mutation (SNP) | VAF 48/670 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2
- CEP170B | c.3389C>T p.A1130V (on ENST00000453495; = p.A1059V on NM_015005.3) | Missense Mutation (SNP) | VAF 60/742 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CEP78 | c.2042A>G p.E681G (on ENST00000424347 / NM_001349840.2; = p.E682G on NM_032171.3) | Missense Mutation (SNP) | VAF 29/424 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.028); called by muse, mutect2
- COL4A6 | c.4583A>C p.N1528T | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); called by muse, mutect2
- COL6A6 | c.2144C>G p.T715S | Missense Mutation (SNP) | VAF 40/556 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CREBRF | c.890A>C p.E297A | Missense Mutation (SNP) | VAF 56/571 reads (10%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2
- CTCF | c.987G>A p.M329I | Missense Mutation (SNP) | VAF 36/455 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2
- CTNNA3 | c.967T>G p.L323V | Missense Mutation (SNP) | VAF 41/484 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2
- CWC22 | c.1205A>C p.K402T | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- DCLK2 | c.208A>C p.K70Q | Missense Mutation (SNP) | VAF 30/710 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- DDX51 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 55/598 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.036); called by muse, mutect2
- DLC1 | c.1579G>C p.D527H (on ENST00000276297 / NM_001348081.2; = p.D90H on NM_006094.5) | Missense Mutation (SNP) | VAF 40/420 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- DNAH11 | c.8530T>G p.L2844V | Missense Mutation (SNP) | VAF 24/455 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2
- DNM1 | c.575A>C p.E192A | Missense Mutation (SNP) | VAF 22/357 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- DPF2 | c.1013A>T p.N338I | Missense Mutation (SNP) | VAF 17/346 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- DYNC2I2 | c.1415C>T p.P472L | Missense Mutation (SNP) | VAF 31/458 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ELL2 | c.1796A>C p.K599T | Missense Mutation (SNP) | VAF 19/254 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ESRRG | c.332A>G p.D111G | Missense Mutation (SNP) | VAF 47/583 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); called by muse, mutect2
- EVX2 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 60/702 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAT2 | c.3245T>G p.I1082S | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- FAT4 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 34/490 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- FBN1 | c.3548A>C p.N1183T | Missense Mutation (SNP) | VAF 18/401 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); called by muse, mutect2
- FFAR4 | c.73T>G p.F25V | Missense Mutation (SNP) | VAF 46/680 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- FGFR4 | c.1280A>C p.K427T | Missense Mutation (SNP) | VAF 50/654 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, mutect2
- FKBP14 | c.497A>C p.K166T | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.057); called by muse, mutect2
- FNDC7 | c.1486G>T p.G496* | Nonsense Mutation (SNP) | VAF 42/603 reads (7%) | called by muse, mutect2
- GALNT11 | c.583T>G p.F195V | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.026); called by muse, mutect2
- GALNTL6 | c.678A>C p.E226D | Missense Mutation (SNP) | VAF 28/494 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2
- GATA3 | c.8T>C p.V3A | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.275); called by muse, mutect2
- GATB | c.929T>C p.L310P | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); called by muse, mutect2
- GDF6 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 48/750 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- GDF7 | c.1180A>G p.N394D | Missense Mutation (SNP) | VAF 60/630 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GEM | c.283T>G p.F95V | Missense Mutation (SNP) | VAF 43/509 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GJA9 | c.1121A>G p.E374G | Missense Mutation (SNP) | VAF 30/484 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- GPATCH1 | c.1936T>G p.S646A | Missense Mutation (SNP) | VAF 28/430 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.404); called by muse, mutect2
- GPRASP1 | c.2287G>A p.A763T | Missense Mutation (SNP) | VAF 43/328 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GTF3C2 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 27/369 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.532); called by muse, mutect2
- H2AC21 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 28/538 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2
- HNMT | c.34C>T p.H12Y | Missense Mutation (SNP) | VAF 12/343 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- IER5L | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 42/444 reads (9%) | called by muse, mutect2
- IL21R | c.244C>T p.H82Y | Missense Mutation (SNP) | VAF 38/684 reads (6%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.575); called by muse, mutect2
- INTU | c.1492T>G p.F498V | Missense Mutation (SNP) | VAF 15/359 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- IQGAP2 | c.3181T>G p.S1061A | Missense Mutation (SNP) | VAF 31/385 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.027); called by muse, mutect2
- ITPR2 | c.7073T>C p.L2358P | Missense Mutation (SNP) | VAF 28/380 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNJ3 | c.1099A>C p.M367L | Missense Mutation (SNP) | VAF 42/454 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KCNT1 | c.3689T>G p.L1230R (on ENST00000488444; = p.L1235R on NM_020822.3) | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- KDM5C | c.3049C>T p.P1017S | Missense Mutation (SNP) | VAF 32/332 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- KIAA1109 | c.1830T>G p.N610K | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2
- LRP1B | c.6275T>G p.F2092C | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MAGEC2 | c.865G>C p.V289L | Missense Mutation (SNP) | VAF 47/347 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MALRD1 | c.1198T>C p.F400L | Missense Mutation (SNP) | VAF 20/257 reads (8%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.999); called by muse, mutect2
- MARK1 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 43/438 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MIOS | c.535T>C p.Y179H | Missense Mutation (SNP) | VAF 33/408 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.088); called by muse, mutect2
- MPRIP | c.1545A>C p.Q515H | Missense Mutation (SNP) | VAF 53/557 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2
- MTHFSD | c.410T>C p.V137A (on ENST00000360900 / NM_001159377.2; = p.V136A on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/476 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- MYH10 | c.1916T>C p.F639S | Missense Mutation (SNP) | VAF 29/450 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.021); called by muse, mutect2
- MYH8 | c.1841A>C p.K614T | Missense Mutation (SNP) | VAF 27/305 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.13); called by muse, mutect2
- MYO3A | c.4109A>C p.K1370T | Missense Mutation (SNP) | VAF 23/443 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); called by muse, mutect2
- NAV1 | c.2093T>G p.I698S | Missense Mutation (SNP) | VAF 50/662 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); called by muse, mutect2
- NID2 | c.1975T>G p.F659V | Missense Mutation (SNP) | VAF 38/458 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.216); called by muse, mutect2
- NKD1 | c.311A>C p.K104T | Missense Mutation (SNP) | VAF 34/508 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- NPHP4 | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 22/499 reads (4%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.494); called by muse, mutect2
- NRDE2 | c.1206A>C p.K402N | Missense Mutation (SNP) | VAF 38/565 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.218); called by muse, mutect2
- OLFM4 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 14/492 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.023); called by muse, mutect2
- OR1A2 | c.526A>G p.N176D | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2
- OR52N2 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- OR6N1 | c.197T>C p.L66P | Missense Mutation (SNP) | VAF 40/568 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR8G1 | c.647G>A p.C216Y | Missense Mutation (SNP) | VAF 27/315 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.047); called by muse, mutect2
- ORC5 | c.488A>G p.E163G | Missense Mutation (SNP) | VAF 29/358 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.722); called by muse, mutect2
- PCBP3 | c.509T>C p.L170P | Missense Mutation (SNP) | VAF 29/473 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PCDH18 | c.631A>G p.S211G | Missense Mutation (SNP) | VAF 24/404 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2
- PCLO | c.14650T>C p.S4884P | Missense Mutation (SNP) | VAF 32/448 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.435); called by muse, mutect2
- PDGFD | c.764A>C p.K255T | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.113); called by muse, mutect2
- PDZD9 | c.572A>C p.K191T (on ENST00000424898 / NM_001363519.1; = p.K131T on NM_173806.4) | Missense Mutation (SNP) | VAF 22/488 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.188); called by muse, mutect2
- PIEZO2 | c.6365G>A p.S2122N | Missense Mutation (SNP) | VAF 27/412 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.212); called by muse, mutect2
- PKP2 | c.2007C>A p.S669R | Missense Mutation (SNP) | VAF 20/372 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.345); called by muse, mutect2
- PNLIPRP2 | c.1298T>C p.L433P (on ENST00000611850; = p.L434P on NM_005396.5) | Missense Mutation (SNP) | VAF 30/428 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POLK | c.2113G>A p.D705N | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.111); called by muse, mutect2
- PPARGC1A | c.136T>G p.L46V | Missense Mutation (SNP) | VAF 46/516 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- PRKAA2 | c.1614T>G p.D538E | Missense Mutation (SNP) | VAF 30/432 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- PRKG2 | c.2225A>T p.D742V | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PROX1 | c.311A>G p.N104S | Missense Mutation (SNP) | VAF 34/580 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); called by muse, mutect2
- PRPF31 | c.113A>G p.E38G | Missense Mutation (SNP) | VAF 54/821 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.109); called by muse, mutect2
- PRRC2A | c.4282G>A p.G1428S | Missense Mutation (SNP) | VAF 51/733 reads (7%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.984); called by muse, mutect2
- RAD51AP2 | c.3468A>C p.K1156N | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); called by muse, mutect2
- RBMXL1 | c.1160G>A p.R387K | Missense Mutation (SNP) | VAF 13/348 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.636); called by muse, mutect2
- RLF | c.3811A>T p.I1271F | Missense Mutation (SNP) | VAF 35/470 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.025); called by muse, mutect2
- RNF165 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 58/754 reads (8%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2
- RNF17 | c.2562T>A p.N854K | Missense Mutation (SNP) | VAF 19/336 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2
- RP1 | c.2538A>C p.E846D | Missense Mutation (SNP) | VAF 18/431 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.755); called by muse, mutect2
- RPAP2 | c.851A>C p.K284T | Missense Mutation (SNP) | VAF 21/326 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.019); called by muse, mutect2
- RYR1 | c.7193G>T p.R2398L | Missense Mutation (SNP) | VAF 39/586 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.163); called by muse, mutect2
- SAMD3 | c.91A>C p.S31R | Missense Mutation (SNP) | VAF 14/311 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- SAMD9L | c.1222T>C p.S408P | Missense Mutation (SNP) | VAF 15/457 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.748); called by muse, mutect2
- SCN7A | c.1209A>T p.R403S | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2
- SNTG2 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 48/489 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- SPTLC2 | c.1502C>T p.T501I | Missense Mutation (SNP) | VAF 34/431 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SPX | c.13A>G p.R5G | Missense Mutation (SNP) | VAF 17/320 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- STX17 | c.851A>T p.E284V | Missense Mutation (SNP) | VAF 28/436 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.047); called by muse, mutect2
- STXBP6 | c.199C>G p.Q67E | Missense Mutation (SNP) | VAF 29/335 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- TACR2 | c.367T>G p.S123A | Missense Mutation (SNP) | VAF 19/339 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.386); called by muse, mutect2
- TAF1 | c.973C>T p.P325S (on ENST00000373790 / NM_138923.4; = p.P346S on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/272 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TAS2R4 | c.696G>A p.M232I | Missense Mutation (SNP) | VAF 30/525 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.151); called by muse, mutect2
- TCTN2 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.116); called by muse, mutect2
- TDRD15 | c.2707T>C p.Y903H | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.657); called by muse, mutect2
- TENM4 | c.7693G>T p.V2565F | Missense Mutation (SNP) | VAF 40/626 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2
- TFCP2L1 | c.638G>A p.C213Y | Missense Mutation (SNP) | VAF 32/368 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TMEM8B | c.1231A>G p.S411G | Missense Mutation (SNP) | VAF 36/616 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- TMEM91 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 63/731 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TNS2 | c.4062-1G>A p.X1354_splice (on ENST00000314250 / NM_170754.4; = p.X1364_splice on NM_015319.2) | Splice Site (SNP) | VAF 14/400 reads (4%) | called by muse, mutect2
- TSNAXIP1 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 18/227 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2
- TTC8 | c.654A>T p.K218N | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2
- TTN | c.10120A>C p.K3374Q (on ENST00000591111; = p.K3328Q on NM_003319.4) | Missense Mutation (SNP) | VAF 18/247 reads (7%) | PolyPhen possibly damaging (0.59); called by muse, mutect2
- UNC13C | c.5237T>G p.I1746S | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- WDR6 | c.3035T>G p.L1012R | Missense Mutation (SNP) | VAF 40/668 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- ZNF230 | c.448A>G p.S150G | Missense Mutation (SNP) | VAF 26/388 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2
- ZNF449 | c.488G>A p.W163* | Nonsense Mutation (SNP) | VAF 26/358 reads (7%) | called by muse, mutect2
- ZNF462 | c.3746T>G p.L1249R | Missense Mutation (SNP) | VAF 44/616 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.027); called by muse, mutect2
- ZNF462 | c.6071A>G p.K2024R | Missense Mutation (SNP) | VAF 34/556 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); called by muse, mutect2
- ZNF578 | c.1277C>T p.P426L | Missense Mutation (SNP) | VAF 21/395 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.086); called by muse, mutect2
- ZNF646 | c.3439G>A p.A1147T | Missense Mutation (SNP) | VAF 61/624 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.397); called by muse, mutect2
- ZNF730 | c.1283A>G p.E428G | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- A2M | c.66C>T p.D22= | Silent (SNP) | VAF 19/319 reads (6%) | catalogued as rs1397674410; called by muse, mutect2
- ABCA4 | c.4879C>T p.L1627= | Silent (SNP) | VAF 47/376 reads (13%) | called by muse, mutect2, varscan2
- AC099489.1 | c.3582G>A p.K1194= | Silent (SNP) | VAF 36/426 reads (8%) | called by muse, mutect2
- ADAMTS2 | c.2376C>T p.G792= | Silent (SNP) | VAF 32/562 reads (6%) | catalogued as rs779908624, COSV52365463, COSV52368801; ClinVar: likely benign; called by muse, mutect2
- AGBL4 | c.6G>A p.A2= | Silent (SNP) | VAF 30/445 reads (7%) | catalogued as rs1294938916; called by muse, mutect2
- AHNAK | c.9594A>C p.P3198= | Silent (SNP) | VAF 32/458 reads (7%) | called by muse, mutect2
- AHNAK2 | c.4029A>T p.P1343= | Silent (SNP) | VAF 57/390 reads (15%) | catalogued as rs770804535; called by muse, mutect2, varscan2
- AKR7A2 | c.369G>T p.L123= | Silent (SNP) | VAF 38/418 reads (9%) | called by muse, mutect2
- ANGPT4 | c.1404C>T p.H468= | Silent (SNP) | VAF 36/557 reads (6%) | catalogued as rs367995955; called by muse, mutect2
- APOBR | c.9C>T p.F3= | Silent (SNP) | VAF 45/540 reads (8%) | catalogued as COSV60491349; called by muse, mutect2
- ASTN1 | c.660C>T p.A220= | Silent (SNP) | VAF 23/695 reads (3%) | called by muse, mutect2
- BCHE | c.276T>A p.S92= | Silent (SNP) | VAF 28/450 reads (6%) | called by muse, mutect2
- BICRAL | c.399C>T p.S133= | Silent (SNP) | VAF 40/540 reads (7%) | called by muse, mutect2
- CAMSAP1 | c.1245C>T p.F415= | Silent (SNP) | VAF 28/375 reads (7%) | called by muse, mutect2
- CASP10 | c.1458G>A p.R486= | Silent (SNP) | VAF 31/457 reads (7%) | called by muse, mutect2
- CBY2 | c.97A>C p.R33= | Silent (SNP) | VAF 26/328 reads (8%) | called by muse, mutect2
- CHRM2 | c.1020T>G p.T340= | Silent (SNP) | VAF 27/466 reads (6%) | called by muse, mutect2
- CLASP2 | c.4173G>A p.L1391= (on ENST00000359576; = p.L1390= on NM_015097.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 27/387 reads (7%) | called by muse, mutect2
- CLSPN | c.1671G>A p.V557= | Silent (SNP) | VAF 41/517 reads (8%) | called by muse, mutect2
- COL11A1 | c.4266T>G p.P1422= | Silent (SNP) | VAF 16/196 reads (8%) | called by muse, mutect2
- CTU1 | c.384C>T p.D128= | Silent (SNP) | VAF 50/732 reads (7%) | called by muse, mutect2
- CUL3 | c.1410G>A p.L470= | Silent (SNP) | VAF 18/334 reads (5%) | catalogued as rs1231397969; called by muse, mutect2
- DKK2 | c.597C>T p.F199= | Silent (SNP) | VAF 28/447 reads (6%) | called by muse, mutect2
- DNAH2 | c.471T>C p.T157= | Silent (SNP) | VAF 32/504 reads (6%) | called by muse, mutect2
- EGR1 | c.1176C>T p.G392= | Silent (SNP) | VAF 59/616 reads (10%) | catalogued as rs199707977, COSV53521049; called by muse, mutect2
- ERBB4 | c.255C>T p.G85= | Silent (SNP) | VAF 12/358 reads (3%) | called by muse, mutect2
- EYA4 | c.1789A>C p.R597= (on ENST00000531901 / NM_001301013.1; = p.R591= on NM_004100.5) | Silent (SNP) | VAF 27/451 reads (6%) | called by muse, mutect2
- FAM220A | c.213G>A p.G71= | Silent (SNP) | VAF 38/469 reads (8%) | catalogued as rs752252905; called by muse, mutect2
- FAM47C | c.1242C>T p.L414= | Silent (SNP) | VAF 33/393 reads (8%) | called by muse, mutect2
- FSIP2 | c.7890A>G p.K2630= | Silent (SNP) | VAF 26/390 reads (7%) | called by muse, mutect2
- FUT11 | c.150C>G p.P50= | Silent (SNP) | VAF 65/950 reads (7%) | catalogued as rs747899391; called by muse, mutect2
- GABRA2 | c.1215T>G p.A405= | Silent (SNP) | VAF 34/538 reads (6%) | catalogued as COSV62911626; called by muse, mutect2
- GCLM | c.639T>A p.T213= | Silent (SNP) | VAF 28/310 reads (9%) | called by muse, mutect2
- GHR | c.405A>G p.T135= | Silent (SNP) | VAF 23/370 reads (6%) | called by muse, mutect2
- GREB1 | c.2286T>C p.H762= | Silent (SNP) | VAF 36/516 reads (7%) | called by muse, mutect2
- HSD17B11 | c.495C>T p.G165= | Silent (SNP) | VAF 36/508 reads (7%) | called by muse, mutect2
- HTR1D | c.801G>A p.S267= | Silent (SNP) | VAF 64/730 reads (9%) | catalogued as rs559058225; called by muse, mutect2
- IGKV1-27 | c.21T>C p.A7= | Silent (SNP) | VAF 10/271 reads (4%) | called by muse, mutect2
- IQCH | c.2880C>T p.L960= | Silent (SNP) | VAF 31/288 reads (11%) | called by muse, mutect2
- KATNIP | c.2694G>A p.E898= | Silent (SNP) | VAF 46/605 reads (8%) | called by muse, mutect2
- KIF27 | c.540T>G p.G180= | Silent (SNP) | VAF 28/398 reads (7%) | called by muse, mutect2
- KLK14 | c.507C>A p.I169= | Silent (SNP) | VAF 32/552 reads (6%) | called by muse, mutect2
- KMT2A | c.2101A>C p.R701= | Silent (SNP) | VAF 15/382 reads (4%) | called by muse, mutect2
- LRRC4B | c.1971A>G p.R657= | Silent (SNP) | VAF 58/892 reads (7%) | called by muse, mutect2
- LRRC71 | c.780T>A p.G260= | Silent (SNP) | VAF 40/638 reads (6%) | catalogued as COSV61656293; called by muse, mutect2
- MAGEC2 | c.375C>A p.G125= | Silent (SNP) | VAF 38/359 reads (11%) | catalogued as COSV55997761; called by muse, mutect2, varscan2
- MAML3 | c.483G>A p.V161= | Silent (SNP) | VAF 13/313 reads (4%) | called by muse, mutect2
- MROH7 | c.402T>A p.T134= | Silent (SNP) | VAF 44/594 reads (7%) | called by muse, mutect2
- MUC17 | c.5065A>C p.R1689= | Silent (SNP) | VAF 30/520 reads (6%) | called by muse, mutect2
- MYH2 | c.4491T>G p.S1497= | Silent (SNP) | VAF 26/408 reads (6%) | called by muse, mutect2
- MYOM3 | c.3540C>A p.S1180= | Silent (SNP) | VAF 16/284 reads (6%) | called by muse, mutect2
- NAV3 | c.6915T>C p.P2305= (on ENST00000397909 / NM_001024383.2; = p.P2283= on NM_014903.6) | Silent (SNP) | VAF 35/455 reads (8%) | called by muse, mutect2
- NLRP1 | c.2949C>T p.I983= | Silent (SNP) | VAF 36/397 reads (9%) | called by muse, mutect2
- NOC3L | c.1683T>C p.T561= | Silent (SNP) | VAF 11/231 reads (5%) | called by muse, mutect2
- OR2I1P | c.825G>A p.S275= | Silent (SNP) | VAF 32/611 reads (5%) | called by muse, mutect2
- OR5T2 | c.429T>A p.A143= | Silent (SNP) | VAF 31/652 reads (5%) | called by muse, mutect2
- PANK4 | c.774C>T p.Y258= | Silent (SNP) | VAF 41/650 reads (6%) | catalogued as rs145319851; called by muse, mutect2
- PCDHGB6 | c.804C>T p.D268= | Silent (SNP) | VAF 36/482 reads (7%) | called by muse, mutect2
- PEAK1 | c.496A>C p.R166= | Silent (SNP) | VAF 28/462 reads (6%) | called by muse, mutect2
- PLXNA3 | c.183T>G p.T61= | Silent (SNP) | VAF 52/465 reads (11%) | called by muse, mutect2, varscan2
- PRAMEF4 | c.1413G>A p.L471= | Silent (SNP) | VAF 20/356 reads (6%) | catalogued as COSV99339724; called by muse, mutect2
- PRR5L | c.1077C>T p.G359= | Silent (SNP) | VAF 28/528 reads (5%) | called by muse, mutect2
- RBM20 | c.2187A>T p.G729= | Silent (SNP) | VAF 33/647 reads (5%) | called by muse, mutect2
- RIN2 | c.1189C>T p.L397= (on ENST00000255006 / NM_001242581.1; = p.L348= on NM_018993.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/620 reads (6%) | called by muse, mutect2
- ROBO3 | c.468C>T p.N156= | Silent (SNP) | VAF 40/498 reads (8%) | catalogued as rs766578334, COSV67300033; ClinVar: uncertain significance; called by muse, mutect2
- SCN9A | c.5596A>C p.R1866= (on ENST00000303354; = p.R1855= on NM_002977.3) | Silent (SNP) | VAF 25/412 reads (6%) | called by muse, mutect2
- SEPTIN6 | c.747G>A p.K249= | Silent (SNP) | VAF 36/233 reads (15%) | called by muse, mutect2, varscan2
- SLC12A6 | c.2244A>G p.G748= (on ENST00000354181 / NM_001365088.1; = p.G697= on NM_005135.2) | Silent (SNP) | VAF 21/341 reads (6%) | called by muse, mutect2
- SORCS3 | c.171T>C p.S57= | Silent (SNP) | VAF 63/854 reads (7%) | called by muse, mutect2
- STOX1 | c.471A>C p.A157= | Silent (SNP) | VAF 10/232 reads (4%) | called by muse, mutect2
- SYNE1 | c.19125G>A p.Q6375= (on ENST00000367255 / NM_182961.4; = p.Q6304= on NM_033071.3) | Silent (SNP) | VAF 31/372 reads (8%) | called by muse, mutect2
- TACSTD2 | c.690C>T p.I230= | Silent (SNP) | VAF 58/656 reads (9%) | called by muse, mutect2
- TAF6L | c.1716C>T p.R572= | Silent (SNP) | VAF 69/780 reads (9%) | catalogued as rs1248034242; called by muse, mutect2
- TMCC2 | c.738C>T p.I246= | Silent (SNP) | VAF 32/389 reads (8%) | catalogued as rs910054861, COSV58002480, COSV58004946; called by muse, mutect2
- ZBTB39 | c.975C>T p.D325= | Silent (SNP) | VAF 50/579 reads (9%) | called by muse, mutect2
- ZNF497 | c.786C>T p.A262= | Silent (SNP) | VAF 51/727 reads (7%) | catalogued as rs745415050; called by muse, mutect2
- ZSCAN26 | c.1308C>T p.H436= (on ENST00000623276 / NM_001111039.2; = p.H302= on NM_152736.5) | Silent (SNP) | VAF 25/424 reads (6%) | called by muse, mutect2
- ZYX | c.1290G>A p.A430= | Silent (SNP) | VAF 32/511 reads (6%) | catalogued as rs559675418, COSV51976738; called by muse, mutect2
- AL353804.7 | chrX:73847977 A>C | 5'Flank (SNP) | VAF 29/223 reads (13%) | called by muse, mutect2, varscan2
- ANKS1B | c.3672+5507A>G | Intron (SNP) | VAF 21/376 reads (6%) | called by muse, mutect2
- ARMCX4 | c.1038+698A>G | Intron (SNP) | VAF 31/320 reads (10%) | called by muse, mutect2, varscan2
- C2CD6 | c.1581+3900A>C | Intron (SNP) | VAF 26/290 reads (9%) | called by muse, mutect2
- DCHS2 | n.814A>T | RNA (SNP) | VAF 29/360 reads (8%) | called by muse, mutect2
- KLF7 | c.*358A>C | 3'UTR (SNP) | VAF 21/506 reads (4%) | called by muse, mutect2
- MEF2D | c.396+77G>A | Intron (SNP) | VAF 32/432 reads (7%) | catalogued as rs1451628265; called by muse, mutect2
- MLIP | c.613-11253C>T | Intron (SNP) | VAF 22/502 reads (4%) | called by muse, mutect2
- MYO3A | c.*87A>G | 3'UTR (SNP) | VAF 46/658 reads (7%) | called by muse, mutect2
- OLFM1 | chr9:135087377 G>A | 5'Flank (SNP) | VAF 52/549 reads (9%) | called by muse, mutect2
- OR2T2 | chr1:248442033 T>G | 5'Flank (SNP) | VAF 33/612 reads (5%) | called by muse, mutect2
- SAXO2 | c.53+2804T>C | Intron (SNP) | VAF 19/258 reads (7%) | called by muse, mutect2
- SEPTIN5 | c.55-858T>A | Intron (SNP) | VAF 36/514 reads (7%) | called by muse, mutect2
- SNX24 | c.60+45403G>A | Intron (SNP) | VAF 23/315 reads (7%) | called by muse, mutect2
- TTN | c.10360+4349A>G | Intron (SNP) | VAF 26/366 reads (7%) | called by muse, mutect2
- TTN | c.10360+1514T>G | Intron (SNP) | VAF 15/343 reads (4%) | called by muse, mutect2
- TXNDC8 | c.255+2276A>G | Intron (SNP) | VAF 26/318 reads (8%) | called by muse, mutect2
- UNC13B | c.762-2815C>A | Intron (SNP) | VAF 36/461 reads (8%) | called by muse, mutect2
- WHRN | c.1167-96A>C | Intron (SNP) | VAF 32/592 reads (5%) | called by muse, mutect2
- ZZZ3 | c.-303G>A | 5'UTR (SNP) | VAF 32/394 reads (8%) | called by muse, mutect2
